Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A7NN, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A7NN-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -

- A. METASTATIC TUMOUR IS PRESENT IN THREE OUT OF TWELVE LYMPH NODES (3/12) EXAMINED.
- B. LARGEST METATSTATIC FOCUS MEASURES 0.4CM.
- C. EXTRACAPSULAR EXTENSION IS NOT IDENTIFIED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN THIRTEEN (0/13) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 4 + 3 = 7 WITH TERTIARY GLEASON PATTERN 5.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.9CM (slide 3U).
- C. THE CARCINOMA INVOLVES 25-30% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION.
- E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE MID AND BASE OF RIGHT POSTERIOR REGION (slides 3V AND 3W).
- F. CARCINOMA INVOLVES BILATERAL SEMINAL VESICLES.
- G. CARCINOMA FOCALLY INVOLVES THE SURGICAL RESECTION MARGINS IN THE REGION OF RIGHT POSTERIOR APEX AND BASE (slides 3U, 3W) AND THE SOFT TISSUE MARGIN AT THE BASE OF RIGHT SEMINAL VESICLE AND VASDEFERENS (slides 3A, 3B).
- H. PERINEURAL INVASION IS IDENTIFIED (slides 3V, 3W, 3X).
- I. ANGIOLYMPHATIC INVASION IS IDENTIFIED (slide 3A, 3C).
- J. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- K. PATHOLOGIC TNM STAGE: PT3b N1 MX.
- L. TNM HISTOLOGIC GRADE = G3-4.
- M. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC PROSTATITIS ARE NOTED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 9.77
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	60%
WEIGHT OF PROSTATE:	40.82gm
TUMOR SIZE:	Maximum dimension: 1.9 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	Yes
SEMINAL VESICLE INVASION:	Yes
SURGICAL MARGIN INVOLVEMENT:	Widespread tumor involvement at margin
LYMPH NODES EXAMINED:	25
LYMPH NODES POSITIVE:	3
EXTRANODAL EXTENSION:	No
SIZE OF NODAL METASTASIS:	4mm
T STAGE, PATHOLOGIC:	pT3b
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

ICD-O-3
Adenocarcinoma, acinar
8140/3
Site Prostate NOS
C61.9
JW 9/24/13

Source: NCI Genomic Data Commons file 59b3b8a2-6e57-4f05-bb64-43ebbe0fe0ed (TCGA-EJ-A7NN.4027496E-5E84-4502-BD86-980339AD9896.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).